Surgical pathology report (de-identified scan), TCGA case TCGA-78-7143, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7143-01A (Primary Tumor).

[page 1 of 2]
A: LEFT UPPER LOBECTOMY

Macroscopy:

Specimen consists of lobe 70mm in diameter; near the hilum there is consolidation 40mm in diameter and possibly some white tumour adjacent. The pleura is not invaded.

Microscopy:

Sections show a well differentiated bronchiolo-alveolar carcinoma. The lung away from the tumour appears normal. The excision margins are clear. Two intrapulmonary lymph nodes (N11L) are negative for tumour.

Summary: Left upper lobectomy: Well differentiated bronchiolo-alveolar carcinoma.

/Over

B: LYMPH NODES No. 7

Macroscopy:

Specimen consists of 7mm node; bisected and blocked in toto.

Microscopy:

Sections show two lymph nodes negative for tumour.

C: LYMPH NODES 5L

Macroscopy:

Specimen consists of fat and nodes 25 x 20 x 5mm. Nodes embedded.

Microscopy:

Sections show two lymph nodes negative for tumour.

c.c. Cancer registry.

[page 2 of 2]
Anatomical Pathology Continued

Final

Pathologist: DR [REDACTED] Registrar: UNKNOWN PATHOLOGIST/REGISTRAR

Report validated by pathologist/registrar

Archive Report

Source: NCI Genomic Data Commons file bc788e65-b840-43ee-8628-8ab5d48e769a (TCGA-78-7143.083BD90A-B596-4A8B-84F5-97CA17CEE7FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).